Somatic mutation profile of tumor specimen TCGA-EB-A5SH-06A (aliquot TCGA-EB-A5SH-06A-11D-A30X-08) from TCGA case TCGA-EB-A5SH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.9 years (22,985 days).
Specimen TCGA-EB-A5SH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52f71b38-16a4-4b51-844c-b1aa4842ea14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5SH-10A (Blood Derived Normal), aliquot TCGA-EB-A5SH-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7284f8c-7276-48f0-af79-dea9777411d7

The open-access MAF lists 98 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 72, Silent 19, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV50789184; called by muse, mutect2, varscan2
- ADAMTS3 | c.2629G>T p.D877Y | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54386714; called by muse, mutect2, varscan2
- ALG8 | c.179C>G p.T60S | Missense Mutation (SNP) | VAF 20/626 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV55199424; called by muse, mutect2
- C1QC | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 48/101 reads (48%) | catalogued as COSV65889335; called by muse, mutect2, varscan2
- C1QTNF2 | c.308G>A p.G103E (on ENST00000393975; = p.G58E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67432460; called by muse, mutect2
- C8B | c.76A>T p.S26C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV64776675; called by muse, varscan2
- C9orf152 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV68762725; called by muse, mutect2
- CAMK4 | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56664375; called by muse, mutect2, varscan2
- CGNL1 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs147998969; called by muse, mutect2, varscan2
- CLUH | c.3389C>T p.A1130V (on ENST00000435359; = p.A1169V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368091556, COSV70928015; called by muse, mutect2, varscan2
- CMPK2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs367867501, COSV56774067; called by muse, mutect2, varscan2
- CNTNAP2 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs1297941346, COSV62152414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSAD | c.1139G>A p.R380H (on ENST00000444623 / NM_001244705.2; = p.R407H on NM_015989.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.713); catalogued as rs746587061, COSV57241642; called by muse, mutect2, varscan2
- DNAJC28 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV58721284; called by muse, mutect2, varscan2
- DPP6 | c.2480C>T p.T827I (on ENST00000377770 / NM_001364500.2; = p.T765I on NM_001936.5) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.116); catalogued as COSV59601571; called by muse, mutect2, varscan2
- DSG1 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57133775; called by muse, mutect2, varscan2
- FBXO2 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.975); catalogued as COSV62813357; called by muse, mutect2, varscan2
- FREM1 | c.5494C>T p.P1832S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV66518987; called by muse, mutect2, varscan2
- FRMPD4 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs886910816, COSV66212019; called by muse, mutect2, varscan2
- GALNTL6 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV72489825, COSV72491503; called by muse, mutect2, varscan2
- GLA | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54508347; called by muse, mutect2, varscan2
- GNPTAB | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54777570; called by muse, mutect2, varscan2
- HIVEP2 | c.6970G>A p.E2324K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV50006419; called by muse, mutect2, varscan2
- HIVEP2 | c.6394A>T p.R2132* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99171532; called by muse, mutect2, varscan2
- IFT22 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1214295390, COSV59526888; called by muse, mutect2, varscan2
- IGHMBP2 | c.1787G>T p.R596M | Missense Mutation (SNP) | VAF 76/726 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54820530; called by muse, varscan2
- INPP5A | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV61247095; called by muse, mutect2, varscan2
- KIT | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as CM1313110, COSV55391254, COSV55433753; called by muse, mutect2, varscan2
- KMT5B | c.2216A>T p.N739I | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV58564251; called by muse, mutect2
- LZIC | c.570dup p.*191Mfs*8 | Frame Shift Ins (INS) | VAF 49/170 reads (29%) | catalogued as rs753028254; called by mutect2, varscan2
- MAD1L1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs77541266, COSV56228204; called by muse, mutect2, varscan2
- MAEL | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV63304125; called by muse, mutect2, varscan2
- MAGEB18 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV57463478; called by muse, mutect2, varscan2
- MAGI1 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100443200, COSV58317356; called by muse, mutect2, varscan2
- MAP4K3 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55710775; called by muse, mutect2, varscan2
- MATN3 | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV68099468; called by muse, mutect2
- MCHR1 | c.96C>G p.N32K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV50760502; called by muse, mutect2, varscan2
- MECOM | c.1636C>A p.Q546K (on ENST00000468789 / NM_001105078.4; = p.Q734K on NM_004991.4) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV52960825; called by muse, mutect2, varscan2
- MKI67 | c.4799A>G p.H1600R | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV64073043; called by muse, mutect2
- NFATC2 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 75/212 reads (35%) | catalogued as COSV65353723; called by muse, mutect2, varscan2
- NTRK3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58112376; called by muse, mutect2, varscan2
- NUDT3 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV70444381; called by muse, varscan2
- NUP62CL | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV65235427; called by muse, mutect2, varscan2
- PCDHB8 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs782228851, COSV99175994; called by muse, varscan2
- PCP4 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV60786339; called by muse, mutect2, varscan2
- PCSK7 | c.2164T>A p.S722T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as COSV54063001; called by muse, mutect2, varscan2
- PITX2 | c.407G>C p.R136P (on ENST00000354925 / NM_001204397.1; = p.R143P on NM_000325.6) | Missense Mutation (SNP) | VAF 80/115 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM024244, COSV100146552, COSV60740376, COSV60741497; called by muse, mutect2, varscan2
- PLEC | c.5925G>C p.K1975N (on ENST00000322810 / NM_201380.4; = p.K1865N on NM_000445.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59610258; called by muse, mutect2, varscan2
- PLEKHA6 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1264601506, COSV55330944; called by muse, mutect2, varscan2
- PPP6R3 | c.1873G>A p.E625K (on ENST00000393800 / NM_001352375.2; = p.E545K on NM_018312.5) | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV55722499; called by muse, mutect2
- PRKCB | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs757200847, COSV57769545; called by muse, mutect2, varscan2
- PRUNE2 | c.7893G>T p.Q2631H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV65038594; called by muse, mutect2, varscan2
- PSG11 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV60453947; called by muse, mutect2, varscan2
- PSG5 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61653676; called by muse, mutect2, varscan2
- PTPN22 | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.475); catalogued as COSV63084422; called by muse, mutect2, varscan2
- PTPRB | c.3554A>C p.N1185T | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV54234729; called by muse, mutect2
- PTPRB | c.3285G>C p.E1095D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.464); catalogued as rs1350202531, COSV54234775, COSV54255703; called by muse, mutect2, varscan2
- REPS2 | c.1973C>G p.T658S | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.339); catalogued as COSV58179801; called by muse, mutect2, varscan2
- RTL4 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61205737, COSV61206676; called by muse, mutect2, varscan2
- SCN5A | c.4853C>T p.S1618F (on ENST00000333535 / NM_198056.3; = p.S1617F on NM_000335.5) | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100345795, COSV61118064; called by muse, mutect2, varscan2
- SLC26A8 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as rs1562019525, COSV62884853; called by muse, mutect2, varscan2
- SP140 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as COSV59447138; called by muse, mutect2, varscan2
- STK32A | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV60415776; called by muse, mutect2, varscan2
- STYK1 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV50012536, COSV50015685; called by muse, mutect2, varscan2
- SYNDIG1 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV65232700; called by muse, mutect2, varscan2
- TAF1 | c.3122G>A p.R1041H (on ENST00000373790 / NM_138923.4; = p.R1062H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV52108677; called by muse, mutect2, varscan2
- TDRD5 | c.1844G>A p.C615Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54239794; called by muse, mutect2, varscan2
- TFB1M | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65698354; called by muse, mutect2, varscan2
- TRAPPC6B | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57527416; called by muse, mutect2, varscan2
- TTN | c.48776A>G p.E16259G (on ENST00000591111; = p.E8835G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | PolyPhen possibly damaging (0.813); catalogued as COSV59920257; called by muse, mutect2, varscan2
- TTN | c.33725C>A p.P11242Q (on ENST00000591111; = p.P10315Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | PolyPhen possibly damaging (0.779); catalogued as COSV59920295, COSV59947848; called by muse, mutect2
- UNC13C | c.3898C>A p.H1300N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV52849206; called by muse, varscan2
- XKR4 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59303108; called by muse, varscan2
- ZNF544 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54134181, COSV54134550; called by muse, mutect2, varscan2
- ZSCAN4 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV58999006, COSV59001307; called by muse, mutect2, varscan2
- ATP10B | c.2693C>A p.P898Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCT6A | c.1328_1331dup p.L444Ffs*16 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- ZNF208 | c.3139del p.H1047Ifs*87 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- DONSON | c.909C>T p.I303= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57387322; called by muse, mutect2, varscan2
- EFR3A | c.690T>A p.P230= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as COSV54454231; called by muse, mutect2, varscan2
- FMN2 | c.3333C>T p.P1111= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV60420418; called by muse, mutect2, varscan2
- GABRB1 | c.1029A>G p.K343= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs780557867, COSV54973441; called by muse, mutect2, varscan2
- GPR1 | c.900C>T p.N300= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1234441605, COSV67976522; called by muse, mutect2, varscan2
- HIVEP2 | c.6393T>C p.P2131= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1562497177, COSV99171533; called by muse, mutect2, varscan2
- HMGN5 | c.21A>T p.A7= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV63916514; called by muse, mutect2, varscan2
- MARK3 | c.1449T>C p.I483= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53507266; called by muse, mutect2, varscan2
- MCF2 | c.2073G>T p.L691= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV58479462; called by muse, mutect2, varscan2
- NID2 | c.3639C>A p.A1213= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV53493815; called by muse, mutect2, varscan2
- OR2Z1 | c.510C>A p.A170= | Silent (SNP) | VAF 49/331 reads (15%) | catalogued as COSV60691855; called by muse, mutect2, varscan2
- OR4X2 | c.702C>A p.S234= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56582493; called by muse, mutect2, varscan2
- PTPRB | c.3552G>A p.R1184= | Silent (SNP) | VAF 93/328 reads (28%) | catalogued as COSV54234752; called by muse, mutect2
- RGS6 | c.492G>A p.A164= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs945946362, COSV59567214; called by muse, mutect2, varscan2
- RP1 | c.531C>A p.T177= | Silent (SNP) | VAF 46/287 reads (16%) | catalogued as COSV55111970; called by muse, mutect2, varscan2
- SLC24A3 | c.1161C>A p.P387= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV60113825; called by muse, mutect2, varscan2
- TRERF1 | c.1963C>A p.R655= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV61668035; called by muse, mutect2, varscan2
- TRIM28 | c.1842A>G p.P614= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV53399079; called by muse, mutect2, varscan2
- ZC3H7B | c.2883T>C p.G961= | Silent (SNP) | VAF 50/239 reads (21%) | catalogued as COSV60960832; called by muse, mutect2, varscan2
